Somatic mutation profile of tumor specimen TCGA-91-8497-01A (aliquot TCGA-91-8497-01A-11D-2393-08) from TCGA case TCGA-91-8497, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.7 years (27,632 days).
Specimen TCGA-91-8497-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7164f90-cccb-4cdc-8f7d-b728d923953f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-8497-10A (Blood Derived Normal), aliquot TCGA-91-8497-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4715acb3-753d-4406-894b-ad2c09f0ef17

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 26, Silent 13, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM2 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99697345, COSV99697588; called by muse, mutect2, varscan2
- ARL6IP1 | c.18T>G p.N6K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV100435945; called by muse, mutect2, varscan2
- ASS1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs752612525, COSV100752721; called by muse, mutect2, varscan2
- BBX | c.2449G>A p.E817K (on ENST00000325805 / NM_001142568.3; = p.E787K on NM_020235.7) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100361897; called by muse, mutect2, varscan2
- CACNA1F | c.5369G>A p.R1790H | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs781946990, COSV59905762; called by muse, mutect2
- CIZ1 | c.2018C>T p.T673I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99476954; called by muse, mutect2, varscan2
- DIDO1 | c.1504A>G p.T502A | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1293720291, COSV99826346; called by muse, mutect2, varscan2
- DNAH7 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557093519, COSV100415994; called by muse, mutect2, varscan2
- GLA | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV99516475; called by muse, mutect2, varscan2
- GPR50 | c.1657C>A p.P553T | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV54437363, COSV99506346; called by muse, mutect2, varscan2
- LYST | c.7160G>A p.R2387Q | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs750886970, COSV101089842; ClinVar: uncertain significance; called by muse, mutect2
- MCM3 | c.604G>T p.V202F (on ENST00000229854 / NM_001366374.2; = p.V192F on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV100008909; called by muse, mutect2
- MCPH1 | c.2055C>A p.H685Q | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100765951; called by muse, mutect2, varscan2
- MEGF8 | c.5809C>T p.R1937C (on ENST00000251268 / NM_001271938.2; = p.R1870C on NM_001410.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs777955709, COSV99237499; called by muse, mutect2, varscan2
- MXRA5 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54238842; called by muse, mutect2, varscan2
- NBEAL2 | c.4051C>G p.P1351A | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as COSV99436587; called by muse, mutect2, varscan2
- NEU1 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99999057; called by muse, mutect2, varscan2
- NKX3-1 | c.329C>A p.S110* | Nonsense Mutation (SNP) | VAF 46/167 reads (28%) | catalogued as rs763879828, COSV101082803; called by muse, mutect2, varscan2
- NPAT | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV99586185; called by muse, mutect2, varscan2
- OR4D9 | c.340T>A p.S114T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs780854690, COSV100259893; called by muse, mutect2, varscan2
- POU3F4 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1437688252, COSV100937152; called by muse, mutect2, varscan2
- SHANK2 | c.2411G>T p.R804L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV99574948; called by muse, mutect2, varscan2
- SRL | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs1281417324, COSV68424710; called by muse, mutect2
- TCF7L2 | c.635C>T p.T212M (on ENST00000355995 / NM_001367943.1; = p.T189M on NM_030756.5) | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs368592547; called by muse, mutect2
- TLL2 | c.1167C>A p.I389= | Splice Region (SNP) | VAF 34/142 reads (24%) | catalogued as COSV100780350, COSV63571552; called by muse, mutect2, varscan2
- TRIP12 | c.17A>G p.N6S | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV99390601; called by muse, mutect2, varscan2
- VSIG1 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99480382; called by muse, mutect2, varscan2
- XYLT1 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 88/475 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99762403; called by muse, mutect2, varscan2
- TNS2 | c.2217del p.L739Ffs*17 (on ENST00000314250 / NM_170754.4; = p.L749Ffs*17 on NM_015319.2) | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | called by mutect2, pindel, varscan2
- VPS13C | c.7697del p.L2566Hfs*7 (on ENST00000644861 / NM_020821.3; = p.L2523Hfs*7 on NM_017684.5) | Frame Shift Del (DEL) | VAF 15/120 reads (13%) | called by mutect2, pindel, varscan2
- ACSF2 | c.1371G>T p.T457= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99366246; called by muse, mutect2, varscan2
- ASPA | c.867C>T p.Y289= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs375736464; called by muse, mutect2, varscan2
- CCNB2 | c.423T>C p.Y141= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV99879097; called by muse, mutect2
- EIF4H | c.633C>A p.L211= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV99733586; called by muse, mutect2
- PCED1A | c.1173C>A p.G391= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as rs1330381279, COSV100642907; called by muse, mutect2, varscan2
- PPP4C | c.288G>T p.L96= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV99661705; called by muse, mutect2, varscan2
- PTPRK | c.3939G>A p.R1313= (on ENST00000368215 / NM_001291984.2; = p.R1314= on NM_002844.4) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV63893209; called by muse, mutect2, varscan2
- R3HDM4 | c.312C>T p.G104= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100846436; called by muse, mutect2, varscan2
- ST8SIA5 | c.897C>T p.I299= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV100164791; called by muse, mutect2, varscan2
- TBC1D22A | c.882G>A p.L294= | Silent (SNP) | VAF 34/153 reads (22%) | catalogued as COSV100453400; called by muse, mutect2, varscan2
- UNC5B | c.1398C>T p.I466= | Silent (SNP) | VAF 11/166 reads (7%) | catalogued as COSV100100943; called by muse, mutect2
- ZNF23 | c.819C>T p.I273= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- ZNF667 | c.1227A>G p.T409= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99410672; called by muse, mutect2, varscan2
